Somatic mutation profile of tumor specimen 0DIR0H from CCDI case PBBRZD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.2 years (4,089 days).
Specimen 0DIR0H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3966e40-f12b-4094-ad52-2bfdc1a7ace1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIQZK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc8a7f00-468b-488e-abe6-eabad78d45f0

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC39A8 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 28/427 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- KRT24 | c.891G>A p.E297= | Silent (SNP) | VAF 62/859 reads (7%) | catalogued as rs200097414; called by muse, mutect2
